Somatic mutation profile of tumor specimen TCGA-D8-A1JP-01A (aliquot TCGA-D8-A1JP-01A-11D-A13L-09) from TCGA case TCGA-D8-A1JP, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 73.5 years (26,862 days).
Specimen TCGA-D8-A1JP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a623c7cf-b154-4f7d-9a11-65cdaa1af67c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1JP-10A (Blood Derived Normal), aliquot TCGA-D8-A1JP-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2a2af24-5a12-4b48-b66c-33ca2d2cd110

The open-access MAF lists 122 somatic variants for this specimen: 95 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 25, Nonsense Mutation 5, Frame Shift Del 4, In Frame Del 3, Splice Site 2, Splice Region 2, 5'UTR 1, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.333G>C p.K111N | Missense Mutation (SNP) | VAF 29/60 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1057519934, COSV55876538, COSV55894288; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC245033.1 | c.1174+2T>G p.X392_splice | Splice Site (SNP) | VAF 13/75 reads (17%) | catalogued as COSV99917324; called by muse, mutect2, varscan2
- ADORA2A | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.585); catalogued as COSV58379706, COSV58380380; called by muse, mutect2, varscan2
- ADORA2A | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as COSV58379713; called by muse, mutect2, varscan2
- BANP | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.91); catalogued as COSV53740199; called by muse, mutect2, varscan2
- BBOF1 | c.156G>C p.K52N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV100592128; called by muse, mutect2
- BCL6 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.115); catalogued as COSV51654092; called by muse, mutect2, varscan2
- BFAR | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55493823, COSV55494252; called by muse, mutect2, varscan2
- BRCA2 | c.5893del p.L1965Ffs*39 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | catalogued as COSV66458259; called by mutect2, pindel, varscan2
- BSND | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV100987595; called by muse, mutect2, varscan2
- C1S | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV61071501; called by muse, mutect2, varscan2
- CCDC136 | c.2708A>C p.K903T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV52802322; called by muse, mutect2, varscan2
- CCDC80 | c.667A>T p.M223L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.372); catalogued as COSV52818571; called by muse, mutect2, varscan2
- CDHR2 | c.1466T>A p.V489E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56142060; called by muse, mutect2, varscan2
- CEP350 | c.8102C>T p.T2701I | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as rs766276755, COSV62606393; called by muse, mutect2, varscan2
- CHD6 | c.3711C>A p.Y1237* | Nonsense Mutation (SNP) | VAF 16/113 reads (14%) | catalogued as COSV58559711; called by muse, mutect2, varscan2
- COL5A3 | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs770509108, COSV53415167; called by muse, mutect2, varscan2
- CRNKL1 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV55638473, COSV99845277; called by muse, mutect2, varscan2
- CYP1A2 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.057); catalogued as COSV59660319; called by muse, mutect2, varscan2
- DNAI1 | c.1625C>G p.S542* | Nonsense Mutation (SNP) | VAF 25/80 reads (31%) | catalogued as COSV54282872; called by muse, mutect2, varscan2
- DYRK1A | c.183G>C p.Q61H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV58295473; called by muse, mutect2, varscan2
- EBF1 | c.1598A>C p.N533T | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV58187155; called by muse, varscan2
- EBF2 | c.599C>G p.T200R | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV101282071; called by muse, mutect2
- EML1 | c.763G>T p.V255L | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1208314885, COSV51748925; called by muse, mutect2, varscan2
- EPRS1 | c.1058A>T p.D353V | Missense Mutation (SNP) | VAF 119/434 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65100358; called by muse, mutect2, varscan2
- FHL2 | c.584T>A p.L195Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59079963; called by muse, mutect2, varscan2
- FIG4 | c.1076T>A p.L359H | Missense Mutation (SNP) | VAF 95/304 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.395); catalogued as COSV57789357; called by muse, mutect2, varscan2
- FOLR1 | c.668A>T p.E223V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.145); catalogued as COSV56616614; called by muse, mutect2, varscan2
- GALR2 | c.213C>A p.D71E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57163732; called by muse, mutect2, varscan2
- GEMIN4 | c.1705G>T p.V569L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV56746698; called by muse, mutect2, varscan2
- GFM2 | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV57192289; called by muse, mutect2, varscan2
- GTF3C1 | c.1609G>A p.G537R | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV62242959; called by muse, mutect2, varscan2
- HSPA2 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV55970677; called by muse, mutect2, varscan2
- KALRN | c.5105C>G p.P1702R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100756583, COSV62571203, COSV62573285; called by muse, mutect2
- KCNK13 | c.816C>G p.I272M | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV56415090; called by muse, mutect2, varscan2
- KMT2C | c.1251T>A p.C417* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as COSV51470367; called by muse, mutect2, varscan2
- KRT73 | c.1468G>T p.G490C | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.606); catalogued as COSV59840419; called by muse, mutect2, varscan2
- LAMB4 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52719880, COSV52724966; called by muse, mutect2, varscan2
- LPA | c.5771G>T p.C1924F | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60305847, COSV60314912; called by muse, mutect2, varscan2
- LRRIQ3 | c.1473C>A p.F491L | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1391465036, COSV100598394; called by muse, mutect2
- LRRK2 | c.3910C>T p.L1304F | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54152088, COSV54161780; called by muse, mutect2, varscan2
- LY9 | c.205A>C p.I69L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.93); catalogued as COSV54435899; called by muse, mutect2, varscan2
- MCTP2 | c.338T>A p.L113H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100537125; called by muse, mutect2
- MIPEP | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.396); catalogued as COSV66301372; called by muse, mutect2, varscan2
- MLLT1 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as COSV53131897, COSV99397885; called by muse, mutect2, varscan2
- MON2 | c.1858A>C p.T620P | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV54811040; called by muse, mutect2, varscan2
- MTHFS | c.270G>C p.M90I | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV51914805; called by muse, mutect2, varscan2
- NKAIN2 | c.193T>C p.Y65H | Missense Mutation (SNP) | VAF 103/678 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV63676119; called by muse, mutect2, varscan2
- NUMB | c.1876A>C p.K626Q (on ENST00000355058; = p.K615Q on NM_003744.5) | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV53720958; called by muse, mutect2, varscan2
- OR10Q1 | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV57470793; called by muse, varscan2
- OR2L3 | c.286T>C p.C96R | Missense Mutation (SNP) | VAF 112/314 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs111507660, COSV63455831; called by muse, mutect2, varscan2
- OR3A1 | c.133A>C p.N45H | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60163513; called by muse, mutect2, varscan2
- OR4K2 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 75/523 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53850708; called by muse, mutect2, varscan2
- OTUD3 | c.677A>T p.D226V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV100908982; called by muse, mutect2, varscan2
- PACSIN2 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs926159807, COSV99605796; called by muse, mutect2
- PAK5 | c.1069C>A p.L357I | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as COSV62032786; called by muse, mutect2, varscan2
- PCNX1 | c.6883C>T p.H2295Y | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as rs1315934650, COSV53097864; called by muse, mutect2, varscan2
- PEX19 | c.280T>G p.L94V | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as COSV63619890; called by muse, mutect2, varscan2
- PGGHG | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as rs377492501, COSV67141218; called by muse, mutect2, varscan2
- PIKFYVE | c.2825A>G p.E942G | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV52245361; called by muse, mutect2, varscan2
- PLPPR4 | c.632G>A p.C211Y | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64566921; called by muse, mutect2, varscan2
- PMEL | c.444C>A p.S148R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as COSV59387390; called by muse, mutect2, varscan2
- PPP6R3 | c.1831C>A p.Q611K (on ENST00000393800 / NM_001352375.2; = p.Q531K on NM_018312.5) | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.87); catalogued as COSV55731727; called by muse, mutect2, varscan2
- PRDM1 | c.1850A>G p.H617R | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64846043; called by muse, mutect2, varscan2
- PRKG1 | c.980C>A p.T327N | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.107); catalogued as rs138485549, COSV64767403; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBM45 | c.1108C>G p.Q370E (on ENST00000616198 / NM_001365579.1; = p.Q368E on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.237); catalogued as COSV53721776; called by muse, mutect2, varscan2
- RNF10 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs1220827722, COSV58046820; called by muse, mutect2, varscan2
- RSBN1 | c.925T>C p.F309L | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.303); catalogued as COSV54733771; called by muse, mutect2, varscan2
- SAMD14 | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs1229603237, COSV99557313; called by muse, mutect2
- SCN9A | c.394A>G p.I132V | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs897659085, COSV57617205; called by muse, mutect2, varscan2
- SGSM2 | c.2801T>C p.V934A (on ENST00000426855 / NM_001098509.2; = p.V979A on NM_014853.3) | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs547672593, COSV51513173; called by muse, mutect2, varscan2
- SHOC1 | c.2741T>G p.V914G | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV59504531; called by muse, mutect2, varscan2
- SIPA1L3 | c.2510C>G p.P837R | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV55919357, COSV99728757; called by muse, mutect2, varscan2
- SLC24A4 | c.1612T>C p.W538R | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100103958; called by muse, mutect2
- SLCO3A1 | c.648A>T p.G216= | Splice Region (SNP) | VAF 65/277 reads (23%) | catalogued as COSV59233697; called by muse, mutect2, varscan2
- SORBS3 | c.1143G>A p.K381= | Splice Region (SNP) | VAF 9/11 reads (82%) | catalogued as COSV53553952; called by muse, mutect2, varscan2
- STARD8 | c.2130A>C p.E710D | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV52929532; called by muse, mutect2, varscan2
- TBC1D8B | c.699G>A p.M233I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV52181266; called by muse, mutect2, varscan2
- TICRR | c.4006G>A p.G1336R | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.015); catalogued as COSV51544152; called by muse, mutect2, varscan2
- TTN | c.72559A>G p.T24187A (on ENST00000591111; = p.T16763A on NM_003319.4) | Missense Mutation (SNP) | VAF 40/118 reads (34%) | PolyPhen benign (0.003); catalogued as COSV60198364; called by muse, mutect2, varscan2
- ZBED4 | c.1913C>T p.A638V | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV53466861; called by muse, mutect2, varscan2
- ZFHX4 | c.1061T>C p.I354T | Missense Mutation (SNP) | VAF 9/289 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.288); catalogued as rs969040934, COSV99254608; called by muse, mutect2
- ZHX2 | c.866A>C p.Q289P | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100072448, COSV58712457; called by muse, mutect2, varscan2
- ZHX3 | c.2146A>G p.I716V | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV58383964, COSV58386187; called by muse, mutect2, varscan2
- ZNF148 | c.2132C>T p.S711F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV62306110; called by muse, mutect2, varscan2
- ZNF346 | c.450G>C p.Q150H | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV56157447; called by muse, mutect2, varscan2
- CASK | c.-21_5del | Translation Start Site (DEL) | VAF 12/29 reads (41%) | called by mutect2, pindel
- GPR156 | c.919_921del p.I307del | In Frame Del (DEL) | VAF 20/69 reads (29%) | called by mutect2, pindel, varscan2
- GRM8 | c.1358-3_1358-2del p.X453_splice | Splice Site (DEL) | VAF 24/146 reads (16%) | called by pindel, varscan2
- KCTD3 | c.146_158del p.S49Kfs*23 | Frame Shift Del (DEL) | VAF 15/97 reads (15%) | called by mutect2, pindel, varscan2
- MKX | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2
- OR2M2 | c.1013_1023del p.K338Ifs*? | Frame Shift Del (DEL) | VAF 24/141 reads (17%) | called by mutect2, pindel, varscan2
- TCFL5 | c.1441_1458delinsA p.L482Tfs*46 | Frame Shift Del (DEL) | VAF 34/169 reads (20%) | called by pindel, varscan2*
- UEVLD | c.900_908del p.Y301_T303del | In Frame Del (DEL) | VAF 31/92 reads (34%) | called by mutect2, pindel, varscan2
- ZUP1 | c.951_956del p.K318_T319del | In Frame Del (DEL) | VAF 44/242 reads (18%) | called by pindel, varscan2
- ANKRD27 | c.768G>T p.V256= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as COSV60133738; called by muse, mutect2, varscan2
- ARFGEF3 | c.5286C>A p.I1762= | Silent (SNP) | VAF 29/42 reads (69%) | catalogued as COSV52463831; called by muse, mutect2, varscan2
- C1QTNF9B | c.456C>T p.G152= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs1287646611, COSV101158651, COSV65944376; called by muse, mutect2, varscan2
- CDK11A | c.1860G>T p.L620= (on ENST00000378633 / NM_001313896.2; = p.L617= on NM_024011.4) | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV52307882; called by muse, mutect2, varscan2
- DAO | c.135C>G p.T45= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV57323662; called by muse, varscan2
- ENTPD6 | c.1207C>T p.L403= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100736944; called by muse, mutect2, varscan2
- FNDC1 | c.4761G>T p.V1587= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs754487880, COSV51943262; called by muse, mutect2, varscan2
- GABRA3 | c.192C>A p.I64= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV64802375; called by muse, mutect2, varscan2
- GNA14 | c.682C>T p.L228= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as COSV59026523; called by muse, mutect2, varscan2
- ITPK1 | c.589C>T p.L197= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs1250102301, COSV50897406; called by muse, mutect2, varscan2
- MCHR2 | c.777C>T p.V259= | Silent (SNP) | VAF 57/308 reads (19%) | catalogued as COSV56005845; called by muse, mutect2, varscan2
- MSH4 | c.1986T>G p.P662= | Silent (SNP) | VAF 37/123 reads (30%) | catalogued as COSV99590348; called by muse, mutect2, varscan2
- MUC16 | c.2322C>A p.T774= | Silent (SNP) | VAF 45/165 reads (27%) | catalogued as COSV67479711; called by muse, mutect2, varscan2
- NCAN | c.12G>T p.P4= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as COSV53054608; called by muse, varscan2
- OR2L3 | c.285G>T p.G95= | Silent (SNP) | VAF 108/310 reads (35%) | catalogued as COSV63455827, COSV63455873; called by muse, varscan2
- OR5F1 | c.460C>T p.L154= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV53547597, COSV99558461; called by muse, varscan2
- P2RY13 | c.429C>G p.L143= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV56387688; called by muse, mutect2, varscan2
- PCM1 | c.5103A>G p.K1701= | Silent (SNP) | VAF 36/70 reads (51%) | catalogued as COSV100278740; called by muse, mutect2, varscan2
- PFKM | c.2118T>C p.D706= | Silent (SNP) | VAF 45/81 reads (56%) | catalogued as COSV56659088; called by muse, mutect2, varscan2
- PIK3C2B | c.2907C>T p.I969= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100915957; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1740G>A p.L580= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV51935736; called by muse, mutect2, varscan2
- SPAG1 | c.1782T>G p.A594= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV99308263; called by muse, mutect2, varscan2
- SYMPK | c.1512T>G p.G504= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV55613628; called by muse, mutect2, varscan2
- ZFPM2 | c.45G>A p.P15= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs1442044896, COSV101343524, COSV68274572; called by muse, mutect2, varscan2
- ZNF112 | c.2319A>C p.G773= (on ENST00000337401 / NM_001083335.2; = p.G767= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 112/331 reads (34%) | catalogued as COSV61621261; called by muse, mutect2, varscan2
- GHRHR | c.*2_*11del | 3'UTR (DEL) | VAF 11/79 reads (14%) | called by mutect2, pindel, varscan2
- RGS8 | c.-133C>A | 5'UTR (SNP) | VAF 43/317 reads (14%) | catalogued as COSV51118089; called by muse, mutect2, varscan2
